Somatic mutation profile of tumor specimen TCGA-25-2401-01A (aliquot TCGA-25-2401-01A-01W-0799-08) from TCGA case TCGA-25-2401, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.9 years (23,711 days).
Specimen TCGA-25-2401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db835e52-469d-45b0-b3d5-e64b06bd576b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2401-10A (Blood Derived Normal), aliquot TCGA-25-2401-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dd57a97-5fa2-4f38-a673-575d3db82762

The open-access MAF lists 92 somatic variants for this specimen: 68 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 21, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 1, 5'Flank 1, RNA 1, Nonstop Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 40/89 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1297A>T p.M433L | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV66068966; called by muse, mutect2, varscan2
- ADAMTS18 | c.646_657del p.G216_G219del | In Frame Del (DEL) | VAF 66/186 reads (35%) | catalogued as COSV51420222; called by mutect2, pindel, varscan2
- ANKRD44 | c.1852G>C p.A618P | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV56561379; called by muse, mutect2, varscan2
- ANKS1A | c.792A>C p.Q264H | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64462851; called by muse, mutect2, varscan2
- ANKS1A | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.193); catalogued as rs766955546, COSV100832836; called by muse, mutect2
- BCL7B | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV56271102; called by muse, mutect2, varscan2
- CCDC80 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV99245331; called by muse, mutect2
- CD53 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 332/1106 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs201712800, COSV54763864; called by muse, mutect2, varscan2
- CLDN18 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as COSV59304062; called by muse, mutect2, varscan2
- CLUL1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 125/758 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as rs751902299, COSV100621035; called by muse, mutect2, varscan2
- CROT | c.1838A>G p.*613Wext*2 | Nonstop Mutation (SNP) | VAF 50/137 reads (36%) | catalogued as COSV55939202; called by muse, mutect2, varscan2
- DAAM1 | c.2495C>G p.A832G | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62838438; called by muse, mutect2, varscan2
- DISP2 | c.4009C>T p.R1337W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778662647, COSV51132791; called by muse, mutect2, varscan2
- DLX5 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56033766; called by muse, mutect2, varscan2
- DPYSL4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.32); catalogued as COSV100634060; called by muse, mutect2, varscan2
- EFHB | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as COSV55551294; called by muse, mutect2, varscan2
- ELAPOR2 | c.1661C>A p.T554N (on ENST00000450689 / NM_001142749.3; = p.T387N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV51889726, COSV99789526; called by muse, mutect2, varscan2
- EXPH5 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56205869; called by muse, mutect2, varscan2
- FGA | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as COSV57394898; called by muse, mutect2, varscan2
- FOXB1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101249938; called by muse, mutect2, varscan2
- FOXB1 | c.272C>G p.P91R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68526281; called by muse, mutect2, varscan2
- FOXJ2 | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV50821153; called by muse, mutect2, varscan2
- GPR162 | c.1643T>C p.V548A (on ENST00000311268 / NM_019858.2; = p.V264A on NM_014449.2) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV51835140; called by muse, mutect2, varscan2
- GSG1L | c.677C>T p.S226F (on ENST00000447459 / NM_001109763.2; = p.S71F on NM_144675.2) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66580770; called by muse, mutect2, varscan2
- HOXA1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56065827; called by muse, mutect2, varscan2
- ITGA1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV50890861; called by muse, mutect2, varscan2
- KCNA1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV101230251, COSV66838239; called by muse, mutect2, varscan2
- KIAA1217 | c.2385G>T p.E795D | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56820622; called by muse, mutect2, varscan2
- KIT | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 11/349 reads (3%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.769); catalogued as COSV99853332, COSV99855360; called by muse, mutect2
- KLC4 | c.1275G>C p.W425C | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52437904; called by muse, mutect2, varscan2
- KRT73 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs1266597163, COSV59840899; called by muse, mutect2, varscan2
- LAMA1 | c.5168A>C p.K1723T | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.434); catalogued as COSV67541202; called by muse, mutect2, varscan2
- LIG3 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52009685; called by muse, mutect2, varscan2
- LTBP1 | c.4664G>A p.G1555E (on ENST00000404816 / NM_206943.4; = p.G1229E on NM_000627.4) | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55382980; called by muse, mutect2, varscan2
- MBTD1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV100899341; called by muse, mutect2
- MTMR12 | c.713+1G>C p.X238_splice | Splice Site (SNP) | VAF 36/768 reads (5%) | catalogued as COSV99374086; called by muse, mutect2
- MTREX | c.2185G>C p.V729L | Missense Mutation (SNP) | VAF 113/377 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV57928544; called by muse, mutect2, varscan2
- MX2 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58098211; called by muse, mutect2, varscan2
- MYL4 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 96/293 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1312335037, COSV61698561; called by muse, mutect2, varscan2
- NEUROD6 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV51769952; called by muse, mutect2, varscan2
- NLRP10 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as COSV60781481; called by muse, mutect2, varscan2
- NLRP6 | c.1027T>G p.C343G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.965); catalogued as COSV100381175; called by mutect2, varscan2
- NRF1 | c.1377C>G p.Y459* | Nonsense Mutation (SNP) | VAF 9/246 reads (4%) | catalogued as COSV56210563; called by muse, mutect2
- OLA1 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV52972552; called by muse, varscan2
- ORC1 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 180/689 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV100856761; called by muse, mutect2, varscan2
- PAIP1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59086845; called by muse, mutect2, varscan2
- PCDHB14 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as COSV53390039, COSV99505765; called by muse, mutect2, varscan2
- PROC | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as CM950997, COSV52167291; called by muse, varscan2
- RYR2 | c.7493C>T p.A2498V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs374191985, CM0910998; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SELP | c.1786T>A p.S596T | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV55255680; called by muse, mutect2, varscan2
- SIGLEC1 | c.4046C>A p.A1349D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99170949; called by muse, mutect2
- SLC20A1 | c.776A>T p.E259V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV55612298; called by muse, mutect2
- SLC6A9 | c.1985G>A p.R662Q (on ENST00000360584 / NM_201649.4; = p.R608Q on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200340553; called by muse, mutect2, varscan2
- SP4 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV56025232; called by muse, mutect2, varscan2
- STXBP3 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749229447, COSV64183079; called by muse, mutect2, varscan2
- SVEP1 | c.7292C>T p.P2431L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99929829; called by muse, mutect2
- TCFL5 | c.1359A>T p.R453S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99416148; called by muse, mutect2, varscan2
- TEP1 | c.5041G>C p.A1681P | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99403261, COSV99403757; called by muse, mutect2
- TLR6 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV67935553, COSV67935599; called by muse, mutect2, varscan2
- USP18 | c.1065C>G p.N355K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as rs1219125087, COSV99306051, COSV99306239; called by muse, mutect2, varscan2
- USP20 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1291503400, COSV59616949; called by muse, mutect2, varscan2
- ZNF236 | c.3943G>A p.V1315I | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV53493768, COSV99468449; called by muse, mutect2, varscan2
- ZNF605 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV59159836; called by muse, mutect2, varscan2
- IGLJ5 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 47/150 reads (31%) | PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- OPHN1 | c.1277-28_1285del p.X426_splice | Splice Site (DEL) | VAF 26/72 reads (36%) | called by mutect2, pindel
- SPAG17 | c.1778_1799del p.N593Rfs*8 | Frame Shift Del (DEL) | VAF 90/510 reads (18%) | called by mutect2, pindel
- SYTL3 | c.1517+4_1517+16del p.X506_splice (on ENST00000611299 / NM_001242394.1; = p.X438_splice on NM_001009991.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- BTNL2 | c.39C>T p.V13= | Silent (SNP) | VAF 26/325 reads (8%) | catalogued as rs1209626047, COSV100896207; called by muse, mutect2
- C3AR1 | c.1329G>A p.R443= | Silent (SNP) | VAF 12/375 reads (3%) | catalogued as COSV50825580; called by muse, mutect2
- CEACAM8 | c.604C>T p.L202= | Silent (SNP) | VAF 314/1987 reads (16%) | catalogued as COSV54991344; called by muse, mutect2, varscan2
- DPYSL4 | c.372G>A p.R124= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100634056; called by muse, mutect2, varscan2
- DPYSL5 | c.1155G>A p.L385= | Silent (SNP) | VAF 9/198 reads (5%) | catalogued as COSV99982807; called by muse, mutect2
- EPB41L3 | c.579T>C p.P193= | Silent (SNP) | VAF 30/235 reads (13%) | catalogued as COSV100550280; called by muse, mutect2, varscan2
- IL3 | c.354C>A p.I118= | Silent (SNP) | VAF 80/384 reads (21%) | catalogued as COSV57309495; called by muse, mutect2, varscan2
- KMT2B | c.4278G>A p.V1426= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV55865923; called by muse, mutect2
- PRAMEF15 | c.798C>T p.F266= | Silent (SNP) | VAF 191/1121 reads (17%) | catalogued as COSV65999894; called by muse, mutect2, varscan2
- RSF1 | c.378C>T p.L126= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs763061072, COSV57843508; called by muse, mutect2, varscan2
- SGIP1 | c.2265G>A p.K755= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52775176, COSV52777196; called by muse, mutect2, varscan2
- SGMS1 | c.753C>T p.D251= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV62371710; called by muse, mutect2, varscan2
- SLC7A3 | c.174C>T p.A58= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99979858; called by muse, mutect2, varscan2
- SNRNP48 | c.477T>G p.A159= | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as COSV100673061; called by muse, mutect2, varscan2
- SOGA1 | c.1653C>T p.H551= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs756752518, COSV52926251; called by muse, mutect2, varscan2
- SP140 | c.2217G>C p.P739= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV59452991; called by mutect2, varscan2
- SPRED1 | c.738C>G p.V246= | Silent (SNP) | VAF 58/189 reads (31%) | catalogued as rs1375963232, COSV54437892; called by muse, mutect2, varscan2
- SV2B | c.792C>T p.G264= | Silent (SNP) | VAF 96/388 reads (25%) | catalogued as COSV57701074, COSV57702478; called by muse, mutect2, varscan2
- ZC3H18 | c.1077C>G p.V359= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV56326748; called by muse, mutect2, varscan2
- ZNF264 | c.1743C>G p.T581= | Silent (SNP) | VAF 33/331 reads (10%) | catalogued as rs1024969386, COSV99567430; called by muse, mutect2
- ZNF804B | c.2796A>G p.V932= | Silent (SNP) | VAF 153/487 reads (31%) | catalogued as COSV60842792; called by muse, mutect2, varscan2
- C3orf35 | n.1320G>T | RNA (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- KIF14 | chr1:200624966 C>T | 5'Flank (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100951086; called by muse, mutect2, varscan2
- RIMS2 | c.1692+230G>C | Intron (SNP) | VAF 9/251 reads (4%) | catalogued as COSV99199871; called by muse, mutect2
